Somatic mutation profile of tumor specimen TCGA-MI-A75H-01A (aliquot TCGA-MI-A75H-01A-11D-A32G-10) from TCGA case TCGA-MI-A75H, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; Age at diagnosis: 77.7 years (28,371 days).
Specimen TCGA-MI-A75H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e9ad9f4-5f6d-4c52-b38d-a5a0ab4a4044.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MI-A75H-10A (Blood Derived Normal), aliquot TCGA-MI-A75H-10A-01D-A32G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/033ca7fc-d903-4b3a-a8e6-3142836aac24

The open-access MAF lists 145 somatic variants for this specimen: 106 protein-altering or splice-affecting, 34 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 34, Nonsense Mutation 7, Frame Shift Del 6, Splice Site 4, 3'UTR 2, Frame Shift Ins 2, RNA 2, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.95A>T p.D32V | Missense Mutation (SNP) | VAF 58/167 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs121913396, COSV62688001, COSV62688037, COSV62688249; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GALC | c.1586C>T p.T529M | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs200960659, CM970565; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.918G>T p.L306F | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV70035273; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2865C>G p.H955Q | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55003252; called by muse, mutect2, varscan2
- AICDA | c.103A>T p.R35W | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as COSV57565222; called by muse, mutect2, varscan2
- ALK | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV66578117; called by muse, mutect2, varscan2
- AMPH | c.15G>T p.K5N | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.541); catalogued as COSV57749070; called by muse, mutect2, varscan2
- AMZ2 | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 17/97 reads (18%) | catalogued as COSV63083461; called by muse, mutect2, varscan2
- APCS | c.277T>C p.Y93H | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.043); catalogued as rs771351516, COSV54818648; called by muse, mutect2, varscan2
- ARHGAP39 | c.564T>A p.D188E | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.057); catalogued as COSV52773293; called by muse, mutect2, varscan2
- ASPSCR1 | c.1568T>A p.V523D | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0.06); catalogued as COSV60716110; called by muse, mutect2, varscan2
- ATP8A1 | c.834+1G>T p.X278_splice | Splice Site (SNP) | VAF 29/65 reads (45%) | catalogued as COSV52540403; called by muse, mutect2, varscan2
- BIN2 | c.506A>T p.K169M | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57206628; called by muse, mutect2, varscan2
- BMPER | c.1880C>T p.T627I | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as rs143727756; called by muse, mutect2, varscan2
- CA10 | c.58T>C p.S20P | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.693); catalogued as COSV53359350; called by muse, mutect2, varscan2
- CAMK2B | c.709G>T p.E237* | Nonsense Mutation (SNP) | VAF 26/63 reads (41%) | catalogued as COSV51661795, COSV51663139; called by muse, mutect2, varscan2
- CEMIP | c.3806T>G p.L1269R | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV54996222; called by muse, mutect2, varscan2
- CLEC3B | c.379A>T p.N127Y | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.368); catalogued as COSV56110056; called by muse, mutect2, varscan2
- COL11A1 | c.2944G>A p.G982R | Missense Mutation (SNP) | VAF 55/182 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62189381; called by muse, mutect2, varscan2
- CRHR1 | c.1195-2A>T p.X399_splice (on ENST00000398285 / NM_001145146.2; = p.X370_splice on NM_004382.5) | Splice Site (SNP) | VAF 4/22 reads (18%) | catalogued as COSV53281829; called by muse, mutect2
- CSRNP3 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58781936; called by muse, mutect2, varscan2
- DCAF4L1 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 61/138 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs754119361, COSV60786850; called by muse, mutect2, varscan2
- DDC | c.636T>A p.D212E | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV63566291; called by muse, mutect2, varscan2
- DNM3 | c.1214C>A p.P405Q | Missense Mutation (SNP) | VAF 96/219 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62462188; called by muse, mutect2, varscan2
- ELOA3 | c.889C>A p.P297T | Missense Mutation (SNP) | VAF 14/215 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV99796169; called by muse, mutect2
- ERAP2 | c.1348T>C p.F450L | Missense Mutation (SNP) | VAF 65/199 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV65940546; called by muse, mutect2
- FANCD2 | c.1742T>C p.M581T | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.857); catalogued as COSV55041736; called by muse, mutect2, varscan2
- FGA | c.1447G>A p.V483M | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.985); catalogued as COSV57398223; called by muse, mutect2, varscan2
- FSIP2 | c.16396A>G p.R5466G | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV58092150; called by muse, mutect2, varscan2
- GABRA6 | c.845C>A p.T282N | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50885852; called by muse, mutect2, varscan2
- GAPVD1 | c.675G>T p.R225S | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52925104; called by muse, mutect2, varscan2
- GIMAP5 | c.890T>C p.F297S | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs752925970, COSV57530185, COSV57530234; called by muse, mutect2, varscan2
- GLB1L | c.1623C>A p.Y541* | Nonsense Mutation (SNP) | VAF 33/112 reads (29%) | catalogued as COSV55477560; called by muse, mutect2, varscan2
- GMPPA | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs756708119, COSV58007713; called by muse, mutect2, varscan2
- GMPS | c.1420G>T p.A474S | Missense Mutation (SNP) | VAF 132/398 reads (33%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs375802837; called by muse, mutect2, varscan2
- HAUS6 | c.2298G>T p.K766N | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV65840337; called by muse, mutect2, varscan2
- HEPH | c.683T>C p.L228P (on ENST00000343002; = p.L282P on NM_138737.5) | Missense Mutation (SNP) | VAF 63/94 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57967575; called by muse, mutect2, varscan2
- HIP1 | c.26A>C p.K9T | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.075); catalogued as COSV61188467; called by muse, mutect2, varscan2
- HNRNPAB | c.874G>T p.G292C | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV57425163; called by muse, mutect2, varscan2
- HOXC9 | c.494T>A p.L165H | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.024); catalogued as COSV100327568; called by muse, mutect2
- HTRA1 | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.094); catalogued as rs1282303354, COSV64564741; called by muse, mutect2, varscan2
- IGHD2-21 | c.11G>T p.W4L | Missense Mutation (SNP) | VAF 23/82 reads (28%) | catalogued as rs781933825; called by muse, mutect2, varscan2
- KCNIP1 | c.599T>C p.I200T (on ENST00000411494 / NM_001034837.3; = p.I189T on NM_014592.4) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as rs757836065, COSV61087320; called by muse, mutect2, varscan2
- KCNV2 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs140256288, CM080425; called by muse, mutect2, varscan2
- KIAA1109 | c.1627G>A p.D543N | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as rs764953885, COSV52682442; called by muse, mutect2, varscan2
- KIR2DL3 | c.751T>A p.S251T | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.965); catalogued as rs758587869, COSV60899042; called by muse, mutect2, varscan2
- KMT2C | c.9968A>C p.H3323P | Missense Mutation (SNP) | VAF 52/149 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs778241763, COSV51466407; called by muse, mutect2, varscan2
- KRTAP1-5 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.874); catalogued as COSV100721394; called by muse, mutect2, varscan2
- KRTAP1-5 | c.286G>T p.G96C | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.95); catalogued as COSV100721395; called by muse, mutect2, varscan2
- LCE5A | c.28T>C p.C10R | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.944); catalogued as COSV57501018; called by muse, mutect2, varscan2
- LMAN1 | c.502A>T p.I168L | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV51828203; called by muse, mutect2, varscan2
- LRP2 | c.5707G>A p.A1903T | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55562207; called by muse, mutect2, varscan2
- MAB21L1 | c.830T>C p.L277P | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV59801619; called by muse, mutect2, varscan2
- MLLT1 | c.544A>T p.K182* | Nonsense Mutation (SNP) | VAF 26/103 reads (25%) | catalogued as COSV53131718; called by muse, mutect2, varscan2
- MLST8 | c.38T>C p.V13A | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV57030094; called by muse, mutect2, varscan2
- MROH5 | c.383A>T p.H128L | Missense Mutation (SNP) | VAF 103/163 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as COSV71302045, COSV71302235; called by muse, mutect2, varscan2
- MUC16 | c.14624C>A p.S4875* | Nonsense Mutation (SNP) | VAF 90/256 reads (35%) | catalogued as rs753313111, COSV67452403; called by muse, mutect2, varscan2
- MUC16 | c.6436C>T p.L2146F | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs935083537, COSV101199598, COSV67464082, COSV67478986; called by muse, mutect2, varscan2
- MYH1 | c.2339T>C p.M780T | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV56852455; called by muse, mutect2, varscan2
- NAP1L2 | c.31T>C p.S11P | Missense Mutation (SNP) | VAF 80/110 reads (73%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.133); catalogued as COSV65172748; called by muse, mutect2, varscan2
- NLRP8 | c.2567G>T p.C856F | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV52590496; called by muse, mutect2, varscan2
- NOTCH3 | c.5140A>T p.M1714L | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs1448731524, COSV54640723; called by muse, mutect2, varscan2
- NUP155 | c.608A>G p.D203G (on ENST00000231498 / NM_153485.3; = p.D144G on NM_004298.4) | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV51532078; called by muse, mutect2, varscan2
- OBSCN | c.11257A>G p.R3753G | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as COSV52797856; called by muse, mutect2, varscan2
- OBSL1 | c.3599C>T p.A1200V | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.963); catalogued as COSV54707948; called by muse, mutect2, varscan2
- OR52B4 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.573); catalogued as rs200224336, COSV68769219; called by muse, mutect2, varscan2
- PCDH15 | c.4835C>T p.T1612I | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious, low confidence (0.03); catalogued as rs754877961, COSV64711367; called by muse, mutect2, varscan2
- PKDREJ | c.3592G>A p.V1198M | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs780697271, COSV53546158; called by muse, mutect2, varscan2
- PKP4 | c.2843A>G p.K948R | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as COSV61579401; called by muse, mutect2, varscan2
- PPDPF | c.257G>A p.S86N | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV64547427; called by muse, mutect2, varscan2
- PRSS38 | c.386G>T p.W129L | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.888); catalogued as COSV64540990; called by muse, mutect2, varscan2
- PYGL | c.581G>T p.R194L | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs758005615, COSV53587096, COSV99368746; called by muse, mutect2, varscan2
- RYR3 | c.1313A>G p.E438G | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV66799961; called by muse, mutect2, varscan2
- SBF2 | c.2807-2A>G p.X936_splice | Splice Site (SNP) | VAF 49/151 reads (32%) | catalogued as COSV56304264; called by muse, mutect2, varscan2
- SCNM1 | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.242); catalogued as rs587766695, COSV54861348; called by muse, mutect2, varscan2
- SIGLEC9 | c.1277T>C p.V426A | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0.009); catalogued as COSV51586088; called by muse, mutect2, varscan2
- SLCO1B1 | c.152C>A p.S51Y | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57009899, COSV57013802; called by muse, mutect2, varscan2
- SPRY3 | c.296T>C p.L99P | Missense Mutation (SNP) | VAF 61/157 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV57143649; called by muse, mutect2, varscan2
- SSX1 | c.502C>A p.L168M | Missense Mutation (SNP) | VAF 161/206 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65355918; called by muse, mutect2, varscan2
- STPG2 | c.659A>T p.N220I | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV54808286; called by muse, mutect2, varscan2
- SULF1 | c.2506C>T p.Q836* | Nonsense Mutation (SNP) | VAF 66/315 reads (21%) | catalogued as COSV52686771; called by muse, mutect2, varscan2
- TET1 | c.1819A>G p.T607A | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV65386767; called by muse, mutect2, varscan2
- TICRR | c.2887A>T p.T963S | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs751853339, COSV51543976; called by muse, mutect2, varscan2
- TMEM132B | c.1286A>T p.E429V | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54760164; called by muse, mutect2, varscan2
- TNK2 | c.632G>T p.G211V | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57372780; called by muse, mutect2, varscan2
- TOGARAM1 | c.4157A>G p.Y1386C | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV63893435; called by muse, mutect2, varscan2
- TRPC6 | c.487del p.D163Mfs*5 | Frame Shift Del (DEL) | VAF 18/70 reads (26%) | catalogued as COSV60251991; called by mutect2, pindel, varscan2
- TSPAN31 | c.311A>C p.Q104P | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57276596; called by muse, mutect2, varscan2
- TTN | c.73355G>A p.G24452E (on ENST00000591111; = p.G17028E on NM_003319.4) | Missense Mutation (SNP) | VAF 39/108 reads (36%) | PolyPhen probably damaging (1); catalogued as COSV60131819; called by muse, mutect2, varscan2
- TTN | c.30997A>C p.K10333Q (on ENST00000591111; = p.K9406Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/104 reads (33%) | PolyPhen benign (0.055); catalogued as COSV60185285; called by muse, mutect2, varscan2
- TUBGCP3 | c.716C>T p.T239M | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.094); catalogued as rs186110739, COSV56186599; called by muse, mutect2, varscan2
- UHRF1BP1L | c.2105G>A p.W702* | Nonsense Mutation (SNP) | VAF 43/128 reads (34%) | catalogued as COSV54439646; called by muse, mutect2, varscan2
- ZNF417 | c.1703G>A p.S568N | Missense Mutation (SNP) | VAF 59/326 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs917372147, COSV56308914; called by muse, mutect2, varscan2
- ZNF502 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV56074233; called by muse, mutect2, varscan2
- ZNF813 | c.1697T>A p.L566H | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as COSV67177287; called by muse, mutect2, varscan2
- ALPG | c.1459del p.L487Wfs*113 | Frame Shift Del (DEL) | VAF 13/40 reads (33%) | called by mutect2, pindel, varscan2
- BBS12 | c.1357_1360dup p.V454Afs*10 | Frame Shift Ins (INS) | VAF 22/75 reads (29%) | called by mutect2, pindel, varscan2
- CDRT1 | c.1429_1430del p.I477Qfs*28 | Frame Shift Del (DEL) | VAF 122/258 reads (47%) | called by mutect2, varscan2
- DNAH11 | c.12788_12790del p.P4263_E4264delinsQ | In Frame Del (DEL) | VAF 37/118 reads (31%) | called by mutect2, pindel, varscan2
- IGKV6-21 | c.56G>C p.G19A | Missense Mutation (SNP) | VAF 72/200 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- KCNA1 | c.226del p.L76* | Frame Shift Del (DEL) | VAF 19/62 reads (31%) | called by mutect2, pindel, varscan2
- NLRP1 | c.1691dup p.L564Ffs*14 | Frame Shift Ins (INS) | VAF 32/109 reads (29%) | called by mutect2, pindel, varscan2
- SAAL1 | c.1166del p.D389Vfs*5 | Frame Shift Del (DEL) | VAF 57/199 reads (29%) | called by mutect2, pindel, varscan2
- SEL1L | c.831_831+11delinsAAAA p.X277_splice | Splice Site (DEL) | VAF 25/143 reads (17%) | called by pindel, varscan2*
- TENM4 | c.4441del p.L1481Cfs*56 | Frame Shift Del (DEL) | VAF 25/80 reads (31%) | called by mutect2, varscan2
- TPTE | c.621T>A p.H207Q (on ENST00000618007 / NM_199261.4; = p.H189Q on NM_199259.4) | Missense Mutation (SNP) | VAF 93/556 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- APCDD1 | c.1536C>A p.I512= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs780464433, COSV62372805; called by muse, mutect2, varscan2
- ARSI | c.855T>C p.G285= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as COSV60817921; called by muse, mutect2, varscan2
- CDK13 | c.1422A>C p.A474= | Silent (SNP) | VAF 37/95 reads (39%) | catalogued as COSV51702966; called by muse, mutect2, varscan2
- CNTFR | c.1047C>A p.P349= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV63634280; called by muse, mutect2, varscan2
- CPVL | c.60T>C p.C20= | Silent (SNP) | VAF 33/97 reads (34%) | catalogued as COSV55305138; called by muse, mutect2, varscan2
- DPP6 | c.1365A>T p.G455= (on ENST00000377770 / NM_001364500.2; = p.G393= on NM_001936.5) | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV59628876; called by muse, mutect2, varscan2
- FBN3 | c.5079T>C p.T1693= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV54465966; called by mutect2, varscan2
- GOLGA8A | c.1764G>A p.Q588= (on ENST00000432566; = p.Q560= on NM_181077.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 33/258 reads (13%) | catalogued as rs763204021, COSV62170426; called by muse, mutect2
- GOLGA8B | c.1680G>A p.Q560= | Silent (SNP) | VAF 17/159 reads (11%) | catalogued as COSV50990943; called by muse, mutect2
- HAPLN4 | c.705G>A p.G235= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as rs752756787, COSV52270379; called by muse, mutect2, varscan2
- IL9R | c.400C>T p.L134= | Silent (SNP) | VAF 36/113 reads (32%) | catalogued as rs776497608, COSV54900886; called by muse, mutect2, varscan2
- ITGB6 | c.777G>T p.R259= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as COSV51796364; called by muse, mutect2
- KLHL4 | c.1059G>T p.V353= | Silent (SNP) | VAF 76/114 reads (67%) | catalogued as COSV64144876; called by muse, mutect2, varscan2
- LRRC31 | c.1269T>A p.S423= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as COSV52981745; called by muse, mutect2, varscan2
- LRRIQ1 | c.2313G>A p.V771= | Silent (SNP) | VAF 56/144 reads (39%) | catalogued as COSV67834267, COSV67838987; called by muse, mutect2, varscan2
- MBD5 | c.2034T>C p.S678= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV68698221; called by muse, mutect2, varscan2
- MCOLN2 | c.1323A>C p.P441= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as COSV52297375; called by muse, mutect2, varscan2
- MECOM | c.516G>T p.S172= (on ENST00000468789 / NM_001105078.4; = p.S360= on NM_004991.4) | Silent (SNP) | VAF 28/65 reads (43%) | catalogued as rs185054275, COSV52969010; called by muse, mutect2, varscan2
- MOV10 | c.177T>C p.Y59= | Silent (SNP) | VAF 30/95 reads (32%) | catalogued as COSV62491963; called by muse, mutect2, varscan2
- NALCN | c.3726A>C p.A1242= | Silent (SNP) | VAF 29/68 reads (43%) | catalogued as COSV51949086; called by muse, mutect2, varscan2
- NOC4L | c.1095G>A p.V365= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as rs375514217; called by muse, mutect2, varscan2
- PHF10 | c.750C>A p.V250= | Silent (SNP) | VAF 36/72 reads (50%) | catalogued as COSV59323219; called by muse, mutect2, varscan2
- PTPRU | c.2010G>C p.A670= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as COSV60531679; called by muse, mutect2, varscan2
- REEP1 | c.321G>A p.L107= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV99383227; called by muse, mutect2, varscan2
- SHANK3 | c.159T>C p.Y53= | Silent (SNP) | VAF 22/30 reads (73%) | catalogued as rs1208475211, COSV53188741; called by muse, mutect2, varscan2
- SLMAP | c.1611T>A p.L537= (on ENST00000428312 / NM_001377924.1; = p.L599= on NM_007159.5) | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as COSV55850243; called by muse, mutect2, varscan2
- SNTG1 | c.1116G>A p.V372= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as rs189241890, COSV52456854; called by muse, mutect2, varscan2
- STK33 | c.970T>C p.L324= | Silent (SNP) | VAF 31/85 reads (36%) | catalogued as COSV59405140; called by muse, mutect2, varscan2
- STPG2 | c.795G>A p.L265= | Silent (SNP) | VAF 92/285 reads (32%) | catalogued as rs1271912172, COSV54808276; called by muse, mutect2, varscan2
- TERF1 | c.981A>G p.Q327= (on ENST00000276603 / NM_017489.3; = p.Q307= on NM_003218.4) | Silent (SNP) | VAF 100/171 reads (58%) | catalogued as COSV52578885; called by muse, mutect2, varscan2
- TMEM87A | c.1329C>T p.A443= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV67747440; called by muse, mutect2, varscan2
- TREML1 | c.207C>T p.R69= | Silent (SNP) | VAF 8/207 reads (4%) | catalogued as COSV100632680; called by muse, mutect2
- TRPM6 | c.750G>A p.L250= | Silent (SNP) | VAF 27/80 reads (34%) | catalogued as COSV62516078; called by muse, mutect2, varscan2
- ZMPSTE24 | c.519G>T p.V173= | Silent (SNP) | VAF 56/200 reads (28%) | catalogued as COSV65639826; called by muse, mutect2, varscan2
- DCHS2 | n.6517G>A | RNA (SNP) | VAF 28/67 reads (42%) | catalogued as COSV61775452; called by muse, mutect2, varscan2
- HERC2P3 | n.1547C>G | RNA (SNP) | VAF 38/139 reads (27%) | called by muse, mutect2, varscan2
- TTN | c.10360+3244G>T | Intron (SNP) | VAF 56/145 reads (39%) | catalogued as COSV60185296; called by muse, mutect2, varscan2
- XIRP2 | c.*1045G>A | 3'UTR (SNP) | VAF 44/137 reads (32%) | catalogued as rs371997749; called by muse, mutect2, varscan2
- ZNF99 | c.*702A>T | 3'UTR (SNP) | VAF 47/100 reads (47%) | catalogued as COSV101233877; called by muse, mutect2, varscan2
